Gene-level copy-number profile of tumor specimen TCGA-28-1747-01C from TCGA case TCGA-28-1747, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 44.6 years (16,301 days).
Specimen TCGA-28-1747-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.7c10cc13-d1d4-445b-9d6c-e2ea021b3949.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-28-1747-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9782b9f9-516f-4264-ab86-1d2ca20569f3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 5,969; copy number 2: 51,681; copy number 3: 2,019; copy number 13: 42; copy number 15: 49; copy number 19: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-28-1747-01C-01D-0784-01): tumor purity 0.8, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–23,849,914, 31 genes (within-gene range 0–1): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1.
- chr10:87,396,561–87,553,461, 5 genes (within-gene range 0–1): FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1.
- chr16:59,088,837–60,053,973, 6 genes (within-gene range 0–1): RPS27P27, AC092121.1, RNU4-58P, DUXAP11, APOOP5, LINC02141.
- chr16:60,346,478–60,499,364, 1 gene (within-gene range 0–1): AC009081.2.
- chr16:60,486,819–60,928,541, 3 genes: AC009081.1, GNPATP, AC009169.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 102 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,721,724–56,340,337, 53 genes, copy number 13–19: AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, AC006970.2, CCNJP1, AC073136.1, AC073136.2, AC093392.1, RNU6-1335P.
- chr7:57,067,950–57,655,392, 49 genes, copy number 15: AC122133.1, ZNF479, AC099654.11, AC099654.2, AC099654.5, AC099654.8, MTATP6P8, MTCO3P10, AC099654.4, MTND4LP32, MTND4P4, MTND5P6, MTND6P29, MTCYBP29, GUSBP10, MTND1P4, MTND2P6, MTCO1P10, MTCO2P10, AC099654.6, MTATP6P10, MTCO3P4, AC099654.9, AC099654.7, MTND4P5, MTND5P7, AC099654.10, MTCYBP5, GUSBP12, AC099654.1, RNU7-157P, AC099654.12, AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3.

Autosomal genes at a single copy (total copy number 1): 3,589. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
